Somatic mutation profile of tumor specimen TCGA-CN-A640-01A (aliquot TCGA-CN-A640-01A-21D-A30E-08) from TCGA case TCGA-CN-A640, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 40.4 years (14,758 days).
Specimen TCGA-CN-A640-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afc0299c-6974-4d97-9b9c-b65567c29dc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A640-10A (Blood Derived Normal), aliquot TCGA-CN-A640-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b312a71-cd07-4da7-96e6-799fa0444ec1

The open-access MAF lists 64 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 41, Silent 14, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALKBH1 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV99380511; called by muse, mutect2, varscan2
- ARFGEF3 | c.3551G>T p.R1184L | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs146602445; called by muse, mutect2, varscan2
- ATRX | c.4754C>T p.S1585F | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64872748; called by muse, mutect2, varscan2
- BCL9 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV52345259; called by muse, mutect2
- BMP15 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV99399328, COSV99399360; called by muse, mutect2, varscan2
- CDKN2A | c.178del p.A60Rfs*86 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as COSV58704370; called by mutect2, varscan2
- CLEC17A | c.667G>C p.A223P | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100355196; called by muse, mutect2, varscan2
- CNTN4 | c.1870C>G p.H624D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV100639129; called by muse, mutect2, varscan2
- COL3A1 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs766679348, COSV100482788; called by muse, mutect2, varscan2
- DMXL2 | c.4042C>T p.H1348Y | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99196173; called by muse, mutect2, varscan2
- EMILIN3 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs780796887, COSV60036525; called by muse, mutect2, varscan2
- FASN | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100147584; called by muse, mutect2, varscan2
- FAT1 | c.10118C>G p.S3373* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV71675300; called by muse, mutect2, varscan2
- FSTL4 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs768871164, COSV54768321; called by muse, mutect2, varscan2
- GPR52 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.821); catalogued as rs1387817607, COSV99269157; called by muse, mutect2, varscan2
- HERC2 | c.11011C>T p.R3671* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99872371; called by muse, mutect2, varscan2
- KCNA4 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV100068791, COSV60251302; called by muse, mutect2, varscan2
- LAMA2 | c.7514C>T p.P2505L | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764060943, COSV70340393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRCH1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100243476; called by muse, mutect2, varscan2
- MDN1 | c.15715G>T p.D5239Y | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV101021054; called by muse, mutect2, varscan2
- NPHS2 | c.774C>G p.I258M | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100858143; called by muse, mutect2, varscan2
- OPCML | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59402511, COSV59438623; called by muse, mutect2
- P2RY14 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99852321; called by muse, mutect2
- PCDH19 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.795); catalogued as rs1405217506, COSV55260451; called by muse, mutect2, varscan2
- PCDHA7 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 53/388 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as COSV100971357, COSV65342644, COSV65343628; called by muse, mutect2, varscan2
- PCLO | c.13133C>A p.A4378D | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100430175; called by muse, mutect2, varscan2
- PEPD | c.866C>A p.T289N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99727566; called by muse, mutect2, varscan2
- PI15 | c.604C>G p.R202G | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.65); catalogued as COSV52641976, COSV99477921; called by muse, mutect2, varscan2
- PTPN3 | c.2419G>A p.V807I | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs750732370, COSV99355584; called by muse, mutect2, varscan2
- RAC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV61821605; called by muse, mutect2, varscan2
- SBF1 | c.3724_3726del p.E1242del | In Frame Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs758613709; called by mutect2, pindel, varscan2
- SCN11A | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs760681852, COSV56566982; called by muse, mutect2, varscan2
- SNAPC2 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1214286372, COSV99563966; called by muse, mutect2, varscan2
- SPTBN4 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs370786781, COSV100150517; called by muse, mutect2, varscan2
- SRRM2 | c.6931C>G p.L2311V | Missense Mutation (SNP) | VAF 66/608 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs1464196809, COSV99241355; called by muse, mutect2, varscan2
- SRRM2 | c.7484C>G p.S2495C | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); catalogued as rs1475922417, COSV99241356; called by muse, varscan2
- STAT4 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV100636004; called by muse, mutect2, varscan2
- SULT1A1 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100131739; called by muse, mutect2, varscan2
- TARDBP | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 22/188 reads (12%) | catalogued as COSV99534104; called by muse, mutect2, varscan2
- THOC2 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99833057; called by muse, mutect2, varscan2
- UNC5C | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV101497845; called by muse, mutect2, varscan2
- USP32 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs768350949, COSV56264446; called by muse, mutect2, varscan2
- VCAM1 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV99658382; called by muse, mutect2
- ZBTB24 | c.1735G>C p.E579Q | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs781753593, COSV100018387; called by muse, mutect2, varscan2
- ZNF462 | c.6400C>G p.P2134A | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99471341; called by muse, mutect2, varscan2
- AKAP8 | c.1193_1236del p.R398Lfs*30 | Frame Shift Del (DEL) | VAF 11/106 reads (10%) | called by mutect2, pindel
- GTF2H4 | c.1329dup p.T444Dfs*18 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.1471_1473dup p.N491dup | In Frame Ins (INS) | VAF 18/174 reads (10%) | called by mutect2, pindel
- SDC4 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- TP53 | c.468_469del p.V157Pfs*23 | Frame Shift Del (DEL) | VAF 32/128 reads (25%) | called by pindel, varscan2
- ACKR1 | c.894G>C p.V298= | Silent (SNP) | VAF 38/432 reads (9%) | catalogued as COSV100929515, COSV63674083; called by muse, mutect2
- ANAPC1 | c.879G>A p.Q293= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100594623; called by muse, mutect2, varscan2
- DROSHA | c.1359G>A p.G453= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV100757557; called by muse, mutect2, varscan2
- IFFO1 | c.1251C>T p.D417= (on ENST00000396840 / NM_001330324.2; = p.D420= on NM_080730.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as rs369387110, COSV60740161; called by muse, mutect2, varscan2
- KIAA1549 | c.3954C>T p.I1318= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV99650357; called by muse, mutect2, varscan2
- LAMA2 | c.1161T>C p.G387= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as COSV101309307, COSV69000606; called by muse, mutect2
- LHX1 | c.69C>T p.A23= | Silent (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2, varscan2
- NLK | c.663G>A p.L221= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1202501336, COSV69408114; called by muse, mutect2
- NRDC | c.2937G>C p.L979= | Silent (SNP) | VAF 50/396 reads (13%) | catalogued as COSV100703266; called by muse, mutect2, varscan2
- RSPH10B2 | c.165G>A p.V55= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as COSV51868748; called by muse, mutect2, varscan2
- SLITRK5 | c.1803C>T p.T601= | Silent (SNP) | VAF 30/272 reads (11%) | catalogued as COSV61521076, COSV61521110; called by muse, mutect2, varscan2
- ST18 | c.2337G>C p.V779= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV99389031; called by muse, mutect2, varscan2
- TSSC4 | c.846G>A p.E282= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99329915; called by muse, mutect2, varscan2
- ZNF586 | c.843G>A p.Q281= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV101197643; called by muse, mutect2, varscan2
